Somatic mutation profile of tumor specimen 1105231 (aliquot 7316UP-613-1105231) from CPTAC case C208854, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Temporal lobe; Tumor grade: G4.
Specimen 1105231: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9aafb5a3-cd7e-41a3-b15d-95654675ccb7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105214 (Blood Derived Normal), aliquot 7316UP-613-1105214; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8f9b5213-5a41-4d58-b6a8-f66ef7b6eb58

The open-access MAF lists 36 somatic variants for this specimen: 24 protein-altering or splice-affecting, 9 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 9, Intron 2, Nonsense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.1793G>T p.G598V | Missense Mutation (SNP) | VAF 822/1177 reads (70%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs139236063, COSV51769031, COSV51808387; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- BAIAP2 | c.859G>A p.V287M | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.022); catalogued as rs943691615; called by muse, mutect2, varscan2
- EDC4 | c.2323G>A p.A775T | Missense Mutation (SNP) | VAF 28/285 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.537); catalogued as rs1214063850; called by muse, mutect2, varscan2
- FLG | c.7407C>G p.S2469R | Missense Mutation (SNP) | VAF 42/538 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.111); catalogued as rs771465526; called by muse, mutect2
- MUC17 | c.8401C>A p.P2801T | Missense Mutation (SNP) | VAF 14/200 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.908); catalogued as rs753157006, COSV60292298; called by muse, mutect2
- MUC4 | c.3575C>G p.S1192* | Nonsense Mutation (SNP) | VAF 22/402 reads (5%) | catalogued as rs1181202036; called by muse, mutect2
- OR51E2 | c.815G>A p.R272H | Missense Mutation (SNP) | VAF 92/537 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs138231892, COSV101211403; called by muse, mutect2, varscan2
- OTOA | c.1138G>A p.V380I (on ENST00000286149; = p.V366I on NM_144672.4) | Missense Mutation (SNP) | VAF 37/420 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.038); catalogued as rs764772897, COSV53750352; called by muse, mutect2
- PENK | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 40/304 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.025); catalogued as rs367716870; called by muse, mutect2, varscan2
- POU5F1B | c.155G>A p.G52E | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.287); catalogued as COSV101197017; called by muse, mutect2
- SHROOM3 | c.1453G>T p.V485L | Missense Mutation (SNP) | VAF 27/297 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.023); catalogued as COSV56026958; called by muse, mutect2
- SUFU | c.190G>C p.G64R | Missense Mutation (SNP) | VAF 47/458 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64015566; called by muse, mutect2, varscan2
- SVEP1 | c.7535C>T p.T2512M | Missense Mutation (SNP) | VAF 25/328 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.727); catalogued as rs200375910; called by muse, mutect2
- TMEM200A | c.1061C>T p.S354L | Missense Mutation (SNP) | VAF 23/144 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.035); catalogued as rs1032893688, COSV51661039; called by muse, mutect2, varscan2
- TRPV5 | c.1327C>T p.R443W | Missense Mutation (SNP) | VAF 20/152 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.245); catalogued as rs775179978, COSV54688182; called by muse, mutect2, varscan2
- VIT | c.1495G>A p.V499I (on ENST00000389975 / NM_001177969.1; = p.V514I on NM_053276.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/243 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.081); catalogued as rs773111980, COSV64899202; called by muse, mutect2
- ZFP64 | c.1756C>G p.L586V | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs371444820, COSV53803673; called by muse, mutect2
- ANKRD40 | c.919G>T p.V307L | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); called by muse, varscan2
- CCDC50 | c.860G>T p.C287F | Missense Mutation (SNP) | VAF 15/138 reads (11%) | SIFT tolerated (0.63); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- CDK17 | c.247T>G p.S83A | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); called by muse, mutect2
- GRID2 | c.1663A>G p.T555A | Missense Mutation (SNP) | VAF 41/352 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- ITGAL | c.200C>A p.T67K | Missense Mutation (SNP) | VAF 5/96 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.28); called by muse, mutect2
- LSR | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 43/342 reads (13%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRM3 | c.305C>A p.P102H | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); called by muse, varscan2
- CFAP61 | c.693G>A p.V231= | Silent (SNP) | VAF 10/92 reads (11%) | called by muse, mutect2
- CRB2 | c.579C>T p.C193= | Silent (SNP) | VAF 13/145 reads (9%) | catalogued as rs758424803; called by muse, mutect2
- GOLGA8H | c.567C>A p.A189= | Silent (SNP) | VAF 30/570 reads (5%) | called by muse, mutect2
- GRHL3 | c.1233C>T p.D411= (on ENST00000350501 / NM_198174.3; = p.D416= on NM_021180.3) | Silent (SNP) | VAF 16/245 reads (7%) | catalogued as rs140971496; called by muse, mutect2
- MSH2 | c.2400A>G p.L800= | Silent (SNP) | VAF 20/139 reads (14%) | catalogued as rs201298777; ClinVar: conflicting interpretations of pathogenicity / uncertain significance / likely benign / benign; called by muse, mutect2, varscan2
- OR6C6 | c.315G>A p.P105= | Silent (SNP) | VAF 16/171 reads (9%) | catalogued as rs751973071; called by muse, mutect2
- PLEKHG3 | c.1986C>T p.D662= (on ENST00000394691; = p.D718= on NM_001308147.2) | Silent (SNP) | VAF 29/340 reads (9%) | called by muse, mutect2
- RYR1 | c.14985T>C p.Y4995= | Silent (SNP) | VAF 18/409 reads (4%) | catalogued as rs1395398890; called by muse, mutect2
- SPHKAP | c.1986C>T p.V662= | Silent (SNP) | VAF 24/189 reads (13%) | catalogued as rs61752224, COSV60872785; called by muse, mutect2, varscan2
- KLC2 | c.*328C>T | 3'UTR (SNP) | VAF 28/270 reads (10%) | catalogued as rs1224502861; called by muse, mutect2
- NCAM1 | c.2456+1105C>T | Intron (SNP) | VAF 21/258 reads (8%) | called by muse, mutect2
- SPINK9 | c.87+30T>C | Intron (SNP) | VAF 16/160 reads (10%) | called by muse, mutect2, varscan2
